FM case AD4791 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/e261bde7-777b-4ca5-8d10-99167cc8e11b

Female, 72.1 years: Carcinosarcoma, NOS (ICD-O-3 8980/3) of the ovary; metastasis biopsied or resected from the pelvis. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
